Somatic mutation profile of tumor specimen TCGA-AP-A05H-01A (aliquot TCGA-AP-A05H-01A-11W-A027-09) from TCGA case TCGA-AP-A05H, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,744 days).
Specimen TCGA-AP-A05H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 969be545-34a8-4512-983c-236bf4355dde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A05H-10A (Blood Derived Normal), aliquot TCGA-AP-A05H-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33e91f84-7f9d-4881-a766-c8678654b46f

The open-access MAF lists 75 somatic variants for this specimen: 62 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 9, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 65/131 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLA | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 86/351 reads (25%) | catalogued as rs886044900, CM138848, COSV54508845; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 71/77 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHRR | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763810046, COSV57084808; called by muse, mutect2, varscan2
- ALG13 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1060500008, COSV52637744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP31 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.429); catalogued as rs1343851131, COSV51791558; called by muse, mutect2, varscan2
- ATP13A3 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 168/850 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.48); catalogued as COSV55463422; called by muse, mutect2, varscan2
- ATP5F1B | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 166/275 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as COSV56260758, COSV56261850; called by muse, mutect2, varscan2
- BRINP1 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.964); catalogued as rs746081030, COSV56297318; called by muse, mutect2, varscan2
- C3 | c.2578C>T p.L860F | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV55571451; called by muse, mutect2, varscan2
- CELA1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV53329578; called by muse, mutect2, varscan2
- CHD4 | c.3445C>T p.R1149W (on ENST00000357008 / NM_001363606.2; = p.R1162W on NM_001273.5) | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894467; called by muse, mutect2, varscan2
- CNTNAP5 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 83/152 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1268035127, COSV70482035; called by mutect2, varscan2
- COL11A1 | c.2321A>T p.K774M | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62180046, COSV62202485; called by muse, mutect2, varscan2
- DDR1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147485952; called by muse, mutect2, varscan2
- DLEC1 | c.2197T>C p.S733P | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57298185; called by muse, mutect2, varscan2
- DMBT1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 126/367 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57540556; called by muse, mutect2, varscan2
- DNAH9 | c.4885C>G p.L1629V | Missense Mutation (SNP) | VAF 75/124 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs543379093, COSV52344833; called by muse, mutect2, varscan2
- DUSP8 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV59029856; called by muse, mutect2, varscan2
- FAT1 | c.3938G>A p.R1313K | Missense Mutation (SNP) | VAF 217/503 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71673359; called by muse, mutect2, varscan2
- FCGR3B | c.265T>C p.C89R | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54209629; called by muse, mutect2, varscan2
- FHL3 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as rs139509332; called by muse, mutect2, varscan2
- FLNA | c.7584C>G p.H2528Q (on ENST00000369850 / NM_001110556.2; = p.H2520Q on NM_001456.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV61041272; called by muse, mutect2, varscan2
- G3BP1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62365957; called by muse, mutect2, varscan2
- GRIA4 | c.1520G>T p.R507L | Missense Mutation (SNP) | VAF 172/273 reads (63%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as COSV56890864; called by muse, mutect2, varscan2
- HEPHL1 | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 66/72 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs554555752, COSV59890415; called by muse, mutect2, varscan2
- HMGXB4 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775566830, COSV53333529; called by muse, mutect2, varscan2
- INPP5F | c.3223C>T p.R1075* | Nonsense Mutation (SNP) | VAF 72/259 reads (28%) | catalogued as rs780378505, COSV62820740; called by muse, mutect2, varscan2
- INTS3 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 245/481 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.228); catalogued as rs886866467, COSV59676695; called by muse, mutect2, varscan2
- ITGA10 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs868991202, COSV65196771, COSV65196822; called by muse, mutect2, varscan2
- ITGA2B | c.2315C>A p.P772Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.209); catalogued as rs531356248, CM093513, COSV52232118; called by muse, mutect2, varscan2
- JADE3 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.118); catalogued as rs782728369, COSV54465718; called by muse, mutect2, varscan2
- KMO | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.422); catalogued as COSV63805912; called by muse, mutect2, varscan2
- LIFR | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54688248; called by muse, mutect2, varscan2
- MS4A3 | c.565A>C p.I189L | Missense Mutation (SNP) | VAF 148/271 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV53935693; called by muse, mutect2, varscan2
- MUC16 | c.21853T>A p.S7285T | Missense Mutation (SNP) | VAF 114/686 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.11); catalogued as rs368093993, COSV101199237; called by muse, mutect2, varscan2
- NEB | c.11742C>A p.Y3914* | Nonsense Mutation (SNP) | VAF 40/141 reads (28%) | catalogued as COSV51100946; called by muse, mutect2, varscan2
- NXPH3 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs377169530, COSV100165507; called by muse, mutect2, varscan2
- PLD5 | c.423C>A p.N141K (on ENST00000442594; = p.N79K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.343); catalogued as COSV59141257; called by muse, mutect2, varscan2
- PLXNA2 | c.369G>T p.E123D | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.073); catalogued as COSV65439764; called by muse, mutect2, varscan2
- POLD1 | c.1911C>A p.F637L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV70954843; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.026); catalogued as COSV53452165; called by muse, mutect2
- PRPF18 | c.505T>G p.L169V | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs756995488, COSV60725010; called by muse, mutect2, varscan2
- PXDN | c.1985G>C p.R662P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53231432, COSV53248644; called by muse, mutect2, varscan2
- SEMA7A | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV56090053; called by muse, mutect2, varscan2
- SLC22A16 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs767217245, COSV57927896, COSV57928998; called by muse, mutect2, varscan2
- SLC5A6 | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs781584176, COSV60159082; called by muse, mutect2, varscan2
- SLC6A9 | c.285C>A p.D95E (on ENST00000360584 / NM_201649.4; = p.D41E on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV62210354; called by muse, mutect2, varscan2
- SLITRK5 | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61522145; called by muse, mutect2, varscan2
- SPEM2 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 678/707 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs754725911, COSV60366583; called by muse, mutect2
- SPIN2B | c.749A>G p.Y250C | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52068893; called by muse, mutect2, varscan2
- TDRD9 | c.1412G>C p.C471S | Missense Mutation (SNP) | VAF 119/554 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV59145335; called by muse, varscan2
- TNN | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as rs1398690138, COSV53424577; called by muse, mutect2, varscan2
- TRIML1 | c.247T>A p.S83T | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV60194001; called by muse, mutect2, varscan2
- TRO | c.353C>A p.A118D | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV51500265; called by muse, mutect2, varscan2
- WDHD1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV62213448; called by muse, mutect2, varscan2
- WDTC1 | c.1987G>A p.D663N (on ENST00000319394 / NM_001276252.2; = p.D662N on NM_015023.5) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV60087963; called by muse, mutect2, varscan2
- ZNF493 | c.1806A>T p.K602N | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV62749758; called by muse, mutect2, varscan2
- ZNF780B | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 119/283 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs372642244, COSV55463425; called by muse, mutect2, varscan2
- PSG9 | c.1143_1179del p.P382Afs*16 | Frame Shift Del (DEL) | VAF 72/314 reads (23%) | called by mutect2, pindel, varscan2
- QTRT1 | c.1074_1098del p.S358Rfs*69 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | called by mutect2, pindel
- REG4 | c.405dup p.N136* | Frame Shift Ins (INS) | VAF 355/646 reads (55%) | called by mutect2, pindel, varscan2
- DHX36 | c.3000A>C p.P1000= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as COSV57671880; called by muse, mutect2, varscan2
- EIF4A1 | c.555C>T p.D185= | Silent (SNP) | VAF 60/207 reads (29%) | catalogued as rs143864020; called by muse, mutect2, varscan2
- HYAL2 | c.1233G>A p.G411= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV63306101; called by muse, mutect2
- LRRC18 | c.624G>A p.A208= | Silent (SNP) | VAF 93/214 reads (43%) | catalogued as rs750366620, COSV53282970; called by muse, mutect2, varscan2
- RAB11FIP4 | c.816T>G p.V272= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV57928041; called by muse, mutect2, varscan2
- SLC1A6 | c.444C>T p.L148= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV55669601; called by muse, mutect2, varscan2
- SMCO1 | c.405C>T p.D135= | Silent (SNP) | VAF 151/315 reads (48%) | catalogued as COSV58837276; called by muse, mutect2, varscan2
- TUT7 | c.1071C>A p.I357= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as COSV52895123; called by muse, mutect2, varscan2
- UNC13C | c.1440C>G p.S480= | Silent (SNP) | VAF 70/184 reads (38%) | catalogued as rs1405506912, COSV52862529; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288241T>C | Intron (SNP) | VAF 42/74 reads (57%) | catalogued as rs555638019; called by muse, mutect2, varscan2
- BMP1 | c.2107+1797C>A | Intron (SNP) | VAF 30/37 reads (81%) | catalogued as COSV60478185; called by muse, mutect2, varscan2
- CHCHD2P9 | n.15C>T | RNA (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22901013 G>A | 3'Flank (SNP) | VAF 10/58 reads (17%) | catalogued as rs7526; called by muse, varscan2
